Gene-level copy-number profile of tumor specimen TCGA-A6-5659-01B from TCGA case TCGA-A6-5659, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 82.2 years (30,028 days).
Specimen TCGA-A6-5659-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.96229008-8c03-499c-896f-da967b353753.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-5659-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/ae17329f-aa6c-463d-b13b-0441fecabf9c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 59,519; copy number 3: 740; copy number 4: 7; copy number 5: 6; copy number 8: 1; copy number 26: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-5659-01A-01D-A274-01): tumor purity 0.85, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:179,220,938–179,222,125, 1 gene, copy number 26: AL512326.3.
- chr6:32,439,878–32,589,848, 6 genes, copy number 5: HLA-DRA, HLA-DRB9, HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr13:28,067,587–28,068,334, 1 gene, copy number 8: KATNBL1P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
